Somatic mutation profile of tumor specimen C3L-01861-02 (aliquot CPT0092290008) from CPTAC case C3L-01861, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.4 years (20,974 days).
Specimen C3L-01861-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d730a7-6508-48aa-9f33-6f6f3892df8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01861-31 (Blood Derived Normal), aliquot CPT0093770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c47d410-49b8-4e68-aa17-fca82ca4580c

The open-access MAF lists 70 somatic variants for this specimen: 49 protein-altering or splice-affecting, 9 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Intron 7, Frame Shift Del 7, Frame Shift Ins 3, 3'UTR 2, In Frame Del 2, 3'Flank 2, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.4240C>T p.Q1414* (on ENST00000372530 / NM_001198934.2; = p.Q1386* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as rs759919213; called by muse, mutect2, varscan2
- FAM71B | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs763029396, COSV100262263; called by muse, mutect2, varscan2
- HDAC9 | c.2370-2A>G p.X790_splice | Splice Site (SNP) | VAF 27/181 reads (15%) | catalogued as COSV67783797; called by muse, mutect2, varscan2
- ID2 | c.24G>C p.R8S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV52170176; called by muse, mutect2
- MAP1B | c.6850G>C p.V2284L | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1156555263; called by muse, mutect2, varscan2
- NLRC3 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369331984; called by muse, mutect2, varscan2
- SEMA3A | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1353490966; called by muse, mutect2, varscan2
- TXNDC11 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1252420989; called by muse, mutect2, varscan2
- USH2A | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as rs754523763, COSV56403480; called by muse, mutect2, varscan2
- ZNF229 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs372929381; called by muse, mutect2, varscan2
- ZNF337 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53323393; called by muse, mutect2, varscan2
- AL035460.1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ASB4 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CCDC168 | c.1718G>C p.G573A | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CEP78 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CHRNG | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CIP2A | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CRNKL1 | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 92/425 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CWC25 | c.416dup p.F140Lfs*17 | Frame Shift Ins (INS) | VAF 28/157 reads (18%) | called by mutect2, pindel, varscan2
- DDX43 | c.1065_1066insT p.D356* | Frame Shift Ins (INS) | VAF 28/138 reads (20%) | called by mutect2, pindel, varscan2
- DMXL2 | c.3619A>G p.S1207G | Missense Mutation (SNP) | VAF 67/408 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC8 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FTH1 | c.115-6T>G | Splice Region (SNP) | VAF 100/552 reads (18%) | called by muse, mutect2, varscan2
- ID2 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- IRS2 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIRREL3 | c.1621del p.A541Pfs*2 | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | called by mutect2, pindel
- KRR1 | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LARP1B | c.457dup p.R153Kfs*19 | Frame Shift Ins (INS) | VAF 44/312 reads (14%) | called by mutect2, pindel, varscan2
- LILRB1 | c.225del p.T76Pfs*6 (on ENST00000427581; = p.T40Pfs*6 on NM_006669.6) | Frame Shift Del (DEL) | VAF 31/205 reads (15%) | called by mutect2, pindel, varscan2
- LRRC10 | c.294del p.K98Nfs*20 | Frame Shift Del (DEL) | VAF 44/268 reads (16%) | called by mutect2, pindel, varscan2
- MLC1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOB3A | c.287del p.K96Sfs*27 | Frame Shift Del (DEL) | VAF 48/235 reads (20%) | called by mutect2, pindel, varscan2
- PARP16 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PBRM1 | c.2614_2625del p.F872_I875del | In Frame Del (DEL) | VAF 46/258 reads (18%) | called by mutect2, pindel, varscan2
- PCF11 | c.1759A>G p.N587D | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDCD6IP | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PIEZO2 | c.2419T>C p.Y807H | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PKD2L2 | c.1679A>C p.Q560P | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- POGLUT3 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- RBSN | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- RECQL | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RHBDL3 | c.1010_1016del p.H337Pfs*20 | Frame Shift Del (DEL) | VAF 60/253 reads (24%) | called by mutect2, pindel, varscan2
- ROCK2 | c.1704T>A p.N568K | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SHANK2 | c.5225G>A p.S1742N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SUMO2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SUPT6H | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- VHL | c.168del p.R58Gfs*9 | Frame Shift Del (DEL) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- XKR6 | c.515_529del p.P172_V176del | In Frame Del (DEL) | VAF 56/269 reads (21%) | called by mutect2, varscan2
- ZNF462 | c.3711_3726del p.C1237* | Frame Shift Del (DEL) | VAF 45/243 reads (19%) | called by mutect2, pindel, varscan2
- F12 | c.495T>A p.G165= | Silent (SNP) | VAF 110/556 reads (20%) | called by muse, mutect2, varscan2
- GPR89A | c.189A>G p.L63= | Silent (SNP) | VAF 12/63 reads (19%) | called by mutect2, varscan2
- LRP2 | c.6381T>A p.I2127= | Silent (SNP) | VAF 76/368 reads (21%) | called by muse, mutect2, varscan2
- LRP2 | c.6246T>C p.D2082= | Silent (SNP) | VAF 71/347 reads (20%) | called by muse, mutect2, varscan2
- MAP2K3 | c.720G>A p.L240= (on ENST00000342679 / NM_145109.3; = p.L211= on NM_002756.4) | Silent (SNP) | VAF 48/451 reads (11%) | catalogued as COSV57567395; called by muse, mutect2, varscan2
- SLC10A7 | c.615C>A p.I205= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- SNX5 | c.654C>T p.N218= | Silent (SNP) | VAF 36/230 reads (16%) | called by muse, varscan2
- TRIM6 | c.945C>A p.V315= | Silent (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- YOD1 | c.102G>A p.A34= | Silent (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195235 del T | 3'Flank (DEL) | VAF 36/120 reads (30%) | called by mutect2, pindel, varscan2
- CABIN1 | c.4117+31C>T | Intron (SNP) | VAF 69/347 reads (20%) | catalogued as rs754732045; called by muse, mutect2, varscan2
- LMOD1 | c.*19C>G | 3'UTR (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- LMOD1 | c.*18C>T | 3'UTR (SNP) | VAF 32/198 reads (16%) | catalogued as rs766264807; called by muse, mutect2, varscan2
- MTMR14 | c.-6T>C | 5'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- MTMR14 | c.1770-30T>G | Intron (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- NAP1L1 | c.1089+234T>A | Intron (SNP) | VAF 38/222 reads (17%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+6363G>C | Intron (SNP) | VAF 32/159 reads (20%) | catalogued as rs1559353296; called by muse, mutect2, varscan2
- SEC14L2 | c.55-902C>A | Intron (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76561186 A>G | 3'Flank (SNP) | VAF 40/136 reads (29%) | called by muse, varscan2
- SYTL2 | c.1459+2771A>T | Intron (SNP) | VAF 43/203 reads (21%) | called by muse, mutect2, varscan2
- TNNT1 | c.129-12C>G | Intron (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
